Somatic mutation profile of tumor specimen C3L-07676-02 (aliquot CPT0411810006) from CPTAC case C3L-07676, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 67.4 years (24,609 days).
Specimen C3L-07676-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 306fc865-dccb-4161-b3c8-114ec20b8f93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07676-31 (Blood Derived Normal), aliquot CPT0411950004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/929979d4-452d-49ea-867b-008d1e1c9944

The open-access MAF lists 221 somatic variants for this specimen: 160 protein-altering or splice-affecting, 56 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 56, Nonsense Mutation 6, Frame Shift Ins 4, Frame Shift Del 4, In Frame Del 3, Intron 2, 5'UTR 1, RNA 1, Splice Site 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 73/259 reads (28%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC126283.2 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs151142273; called by muse, mutect2, varscan2
- ADAMTS6 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs748200907; called by muse, mutect2, varscan2
- AFF2 | c.2474A>G p.K825R | Missense Mutation (SNP) | VAF 134/481 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV53993398; called by muse, mutect2, varscan2
- AGRN | c.2769C>G p.C923W | Missense Mutation (SNP) | VAF 110/482 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65068363; called by muse, mutect2, varscan2
- ANKRD11 | c.4084G>A p.D1362N | Missense Mutation (SNP) | VAF 54/419 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as rs748428674; called by muse, mutect2, varscan2
- AP2B1 | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51997209; called by mutect2, varscan2
- ATP13A2 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs776426461; called by muse, mutect2, varscan2
- C10orf67 | c.161G>A p.R54Q (on ENST00000323327; = p.R55Q on NM_153714.3) | Missense Mutation (SNP) | VAF 50/492 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1403123235; called by muse, mutect2
- C5AR2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 62/822 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs770710671, COSV57255861; called by muse, mutect2
- CDYL2 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as rs772092026, COSV73647784; called by muse, mutect2, varscan2
- CGB3 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 31/716 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.096); catalogued as rs1420097436, CM993878; called by muse, mutect2
- CNGA4 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 52/459 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1443792448, COSV66007222; called by muse, mutect2, varscan2
- DMBX1 | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 69/641 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1381645235; called by muse, mutect2, varscan2
- DNER | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 91/374 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); catalogued as rs772555280, COSV59162827; called by muse, mutect2, varscan2
- ECEL1 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 90/590 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1298500213; called by muse, varscan2
- EOMES | c.995dup p.K333Qfs*11 | Frame Shift Ins (INS) | VAF 102/367 reads (28%) | catalogued as rs1309565164; called by mutect2, pindel, varscan2
- EZR | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs370037610; called by muse, mutect2
- FAM155B | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 156/514 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as COSV52935094; called by muse, mutect2, varscan2
- FAM189B | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 149/648 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs201266020; called by muse, mutect2, varscan2
- FAT3 | c.4007G>A p.R1336H | Missense Mutation (SNP) | VAF 79/324 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs528757478, COSV53091298; called by muse, mutect2, varscan2
- FAT4 | c.8633C>A p.S2878Y | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV58687789; called by muse, mutect2, varscan2
- FER1L5 | c.2981G>A p.R994H (on ENST00000623019; = p.R1001H on NM_001293083.2) | Missense Mutation (SNP) | VAF 56/548 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs915336830; called by muse, mutect2, varscan2
- FERD3L | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 63/523 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51764402; called by muse, mutect2, varscan2
- FLNC | c.4132G>T p.A1378S | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57957628; called by muse, mutect2, varscan2
- GPSM2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs146446929; called by muse, mutect2, varscan2
- GRM1 | c.2420G>A p.G807E | Missense Mutation (SNP) | VAF 47/449 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229875416, COSV99266875; called by muse, mutect2, varscan2
- GRM8 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs751847809; called by muse, mutect2, varscan2
- IGSF1 | c.3521A>C p.K1174T | Missense Mutation (SNP) | VAF 127/441 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV100811778, COSV100811883, COSV63839442; called by mutect2, varscan2
- IGSF9 | c.2443C>T p.R815C (on ENST00000368094 / NM_001135050.2; = p.R799C on NM_020789.4) | Missense Mutation (SNP) | VAF 128/513 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1208207934, COSV100231136; called by muse, mutect2, varscan2
- KCNA5 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 65/483 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs200759249; called by muse, mutect2, varscan2
- KCNV1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747782041, COSV52087001; called by muse, mutect2, varscan2
- KRT9 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769324302; called by muse, mutect2, varscan2
- LAMA2 | c.911A>T p.K304I | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV70358460; called by muse, mutect2, varscan2
- LRFN1 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 89/648 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as COSV50439707; called by muse, mutect2, varscan2
- LRFN5 | c.706A>C p.S236R | Missense Mutation (SNP) | VAF 111/423 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1244908019, COSV53247525, COSV53257646; called by muse, mutect2, varscan2
- MAG | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 52/409 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV62699874; called by muse, mutect2, varscan2
- MAP2K7 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 94/388 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607626; called by muse, mutect2, varscan2
- MFSD8 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 67/413 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.534); catalogued as rs547726489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC2 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT tolerated, low confidence (0.1); catalogued as rs375767205; called by muse, mutect2, varscan2
- MYO19 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763595894; called by muse, mutect2, varscan2
- MYT1L | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 78/411 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1037022282; called by muse, mutect2, varscan2
- NDFIP2 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs1375797605; called by muse, mutect2, varscan2
- NES | c.2287C>G p.Q763E | Missense Mutation (SNP) | VAF 69/484 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV100957873; called by muse, mutect2, varscan2
- NEUROD6 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51770144, COSV51770432; called by muse, mutect2, varscan2
- NFATC2 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 155/821 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65360684; called by muse, mutect2, varscan2
- NRG1 | c.902C>A p.P301Q (on ENST00000405005 / NM_013964.5; = p.P306Q on NM_013956.5) | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as rs888243581; called by muse, mutect2, varscan2
- NRXN2 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 104/389 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as rs1434434360; called by muse, mutect2, varscan2
- OLFM3 | c.257T>G p.L86R (on ENST00000338858 / NM_001288821.1; = p.L66R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58796124, COSV58798328; called by muse, mutect2, varscan2
- OR12D3 | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 76/556 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs1483742497; called by muse, mutect2, varscan2
- OR5T1 | c.823A>G p.S275G | Missense Mutation (SNP) | VAF 60/495 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV57302939; called by muse, mutect2, varscan2
- PCDHA1 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 61/471 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.052); catalogued as rs782199797, COSV65372985; called by muse, mutect2, varscan2
- PLAGL2 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 130/568 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs367867310; called by muse, mutect2, varscan2
- PTPRT | c.1002G>A p.W334* | Nonsense Mutation (SNP) | VAF 141/617 reads (23%) | catalogued as rs1360709532; called by muse, mutect2, varscan2
- PXDNL | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 60/525 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1290248255, COSV62484407; called by muse, mutect2, varscan2
- RAX | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 100/362 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as rs758557521; called by muse, mutect2, varscan2
- RGSL1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs573789337, COSV54264167; called by muse, mutect2, varscan2
- RHOBTB3 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV101183178; called by muse, mutect2
- RIMBP3 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 211/1404 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.103); catalogued as rs1219132873; called by muse, mutect2, varscan2
- RTL1 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 99/421 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1350202171, COSV66016629; called by muse, mutect2, varscan2
- RYR2 | c.4990G>A p.V1664I | Missense Mutation (SNP) | VAF 46/460 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs749434532, COSV63698965, COSV63705585; called by muse, mutect2
- RYR3 | c.12124C>T p.R4042C (on ENST00000389232; = p.R4043C on NM_001036.6) | Missense Mutation (SNP) | VAF 41/339 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs897805506; called by muse, mutect2, varscan2
- SCAP | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV55558892; called by muse, mutect2, varscan2
- SFTPD | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 51/384 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100954573; called by muse, mutect2, varscan2
- SLC13A4 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 47/396 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs769333711, COSV62459878; called by muse, mutect2, varscan2
- SLC6A2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 72/411 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV54912618; called by muse, mutect2, varscan2
- SNRPB | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 74/354 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1350686216, COSV100293569, COSV60014916; called by muse, mutect2, varscan2
- SRRM4 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 85/463 reads (18%) | catalogued as COSV57421499; called by muse, mutect2, varscan2
- STK10 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs374049452; called by muse, mutect2, varscan2
- STRN4 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 81/445 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1323469767, COSV54416645; called by muse, mutect2, varscan2
- TEAD2 | c.1166A>C p.K389T | Missense Mutation (SNP) | VAF 36/467 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV60544175; called by muse, mutect2
- TPH1 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51459303; called by muse, mutect2, varscan2
- TRIM49B | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 66/523 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV60321576, COSV60322163, COSV60324412; called by muse, mutect2, varscan2
- TTC34 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 139/569 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1173030440; called by muse, mutect2, varscan2
- TUBA8 | c.1247_1249del p.G416del | In Frame Del (DEL) | VAF 102/385 reads (26%) | catalogued as rs1336680066; called by mutect2, pindel, varscan2
- USP9X | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV61075632; called by muse, mutect2, varscan2
- WDFY4 | c.5392G>A p.V1798M | Missense Mutation (SNP) | VAF 65/601 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs569179112, COSV55425175; called by muse, mutect2, varscan2
- XIRP2 | c.3678A>C p.E1226D (on ENST00000628543; = p.E1401D on NM_152381.6) | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54696788, COSV54722905, COSV99739657; called by muse, mutect2
- ZMYND8 | c.1382C>T p.A461V (on ENST00000311275 / NM_001363741.2; = p.A481V on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/385 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as rs1157690316, COSV53691887; called by muse, mutect2, varscan2
- ZNF385D | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 93/345 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1034519990, COSV55752967; called by muse, mutect2, varscan2
- A2ML1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 35/294 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADNP | c.1726G>C p.A576P | Missense Mutation (SNP) | VAF 39/580 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.645); called by muse, mutect2
- ALG12 | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 85/329 reads (26%) | called by muse, mutect2, varscan2
- APOC1 | c.6G>T p.R2S | Missense Mutation (SNP) | VAF 128/588 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ATP10A | c.2206C>T p.L736F | Missense Mutation (SNP) | VAF 61/402 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- BECN2 | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 128/591 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- C6 | c.2381+1G>T p.X794_splice | Splice Site (SNP) | VAF 48/324 reads (15%) | called by muse, mutect2, varscan2
- CAGE1 | c.1810C>T p.P604S (on ENST00000512086; = p.P468S on NM_205864.3) | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CCDC105 | c.758A>C p.D253A | Missense Mutation (SNP) | VAF 56/456 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CCNT2 | c.1981G>C p.V661L | Missense Mutation (SNP) | VAF 102/345 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CDRT15L2 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CLECL1 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CRHR1 | c.559C>T p.L187F (on ENST00000398285 / NM_001145146.2; = p.L158F on NM_004382.5) | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CSPG4 | c.6352C>G p.L2118V | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); called by muse, mutect2
- CTAGE1 | c.697C>A p.H233N | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CTAGE1 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- CTC1 | c.2971del p.Y991Mfs*5 | Frame Shift Del (DEL) | VAF 34/259 reads (13%) | called by mutect2, pindel, varscan2
- CXCR5 | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 183/551 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP2E1 | c.619T>C p.F207L | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DACH1 | c.2019G>C p.K673N (on ENST00000619232 / NM_001366712.1; = p.K419N on NM_004392.6) | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DENND2C | c.1867C>A p.P623T (on ENST00000393274 / NM_001256404.2; = p.P566T on NM_198459.4) | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- DLC1 | c.2919_2927del p.E975_P977del (on ENST00000276297 / NM_001348081.2; = p.E538_P540del on NM_006094.5) | In Frame Del (DEL) | VAF 98/395 reads (25%) | called by mutect2, pindel, varscan2
- FAM149B1 | c.1018A>G p.N340D | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.345); called by muse, mutect2
- FBXO10 | c.700T>G p.F234V | Missense Mutation (SNP) | VAF 116/411 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FIGN | c.1327C>A p.Q443K | Missense Mutation (SNP) | VAF 58/479 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOCAD | c.699G>T p.Q233H | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FOXF2 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 67/533 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- FOXQ1 | c.704_711del p.L235Rfs*211 | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | called by mutect2, varscan2*
- FTMT | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 62/567 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA5 | c.1082A>T p.K361M | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- GAK | c.3185G>A p.G1062E | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HS6ST2 | c.527C>A p.T176K | Missense Mutation (SNP) | VAF 57/572 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ISM1 | c.1277G>C p.C426S | Missense Mutation (SNP) | VAF 56/584 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- JMJD1C | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- JUND | c.734_735dup p.V246Rfs*56 | Frame Shift Ins (INS) | VAF 120/547 reads (22%) | called by mutect2, pindel, varscan2
- KHDRBS1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 96/583 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA0100 | c.1096dup p.D366Gfs*35 | Frame Shift Ins (INS) | VAF 39/302 reads (13%) | called by mutect2, pindel, varscan2
- KRT77 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 169/657 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- LCN12 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 65/496 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRTM4 | c.632A>T p.H211L | Missense Mutation (SNP) | VAF 50/370 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPK8IP1 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 63/465 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- MCF2 | c.1435A>C p.S479R | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MYLK | c.3481C>A p.L1161M | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- NELFCD | c.61G>A p.E21K (on ENST00000602795; = p.E3K on NM_198976.4) | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, mutect2
- NLRP14 | c.899A>G p.E300G | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- NLRP5 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 111/571 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- NLRP5 | c.1510G>T p.A504S | Missense Mutation (SNP) | VAF 74/689 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NSUN5 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- NXPE4 | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 184/505 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ONECUT1 | c.204C>G p.Y68* | Nonsense Mutation (SNP) | VAF 186/613 reads (30%) | called by muse, mutect2, varscan2
- OR10G6 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 127/398 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- PAFAH2 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 57/355 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH11X | c.2248T>G p.L750V | Missense Mutation (SNP) | VAF 50/370 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHB8 | c.892T>G p.L298V | Missense Mutation (SNP) | VAF 50/970 reads (5%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.003); called by muse, mutect2
- PDE1C | c.1939A>T p.T647S | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHKA2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PNMA5 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 69/470 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R3A | c.904C>G p.R302G | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2R1A | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- PPP2R5D | c.534C>A p.N178K | Missense Mutation (SNP) | VAF 89/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCI | c.1746del p.F582Lfs*8 | Frame Shift Del (DEL) | VAF 72/290 reads (25%) | called by mutect2, pindel, varscan2
- RAB11FIP2 | c.405G>C p.E135D | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SALL3 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 89/721 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SAMD9 | c.3629T>A p.I1210N | Missense Mutation (SNP) | VAF 79/317 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SDCBP | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC9A2 | c.1336G>A p.V446M | Missense Mutation (SNP) | VAF 77/449 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC9A3 | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 64/810 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- TAB3 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 96/385 reads (25%) | called by muse, mutect2, varscan2
- TGFB3 | c.14dup p.L5Ffs*40 | Frame Shift Ins (INS) | VAF 69/281 reads (25%) | called by mutect2, pindel, varscan2
- TPTE | c.1594G>C p.A532P (on ENST00000618007 / NM_199261.4; = p.A514P on NM_199259.4) | Missense Mutation (SNP) | VAF 69/638 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- TRIM56 | c.154_156del p.G52del | In Frame Del (DEL) | VAF 134/528 reads (25%) | called by pindel, varscan2
- UNC45B | c.2201T>G p.L734R | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- USP17L7 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 68/472 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.216); called by muse, varscan2
- XRN1 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2
- YIPF1 | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZC3H11A | c.280T>G p.F94V | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ZNF223 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 29/381 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ZNF382 | c.53A>C p.Q18P | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ZNF528 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.110del p.N37Ifs*6 | Frame Shift Del (DEL) | VAF 33/248 reads (13%) | called by mutect2, pindel, varscan2
- ADARB2 | c.1791C>T p.R597= | Silent (SNP) | VAF 113/701 reads (16%) | catalogued as rs1164643195; called by muse, mutect2, varscan2
- ANKRD60 | c.129C>T p.A43= | Silent (SNP) | VAF 30/584 reads (5%) | called by muse, mutect2
- ATP13A2 | c.2796C>T p.S932= | Silent (SNP) | VAF 73/314 reads (23%) | catalogued as rs755542233, COSV100453843; called by muse, mutect2, varscan2
- BMP6 | c.363C>T p.R121= | Silent (SNP) | VAF 54/503 reads (11%) | called by muse, varscan2
- CACNG3 | c.354C>A p.G118= | Silent (SNP) | VAF 93/584 reads (16%) | catalogued as rs546224102, COSV50084811; called by muse, mutect2, varscan2
- CALHM3 | c.225G>A p.V75= | Silent (SNP) | VAF 56/360 reads (16%) | called by muse, mutect2, varscan2
- CDH10 | c.1734C>T p.S578= | Silent (SNP) | VAF 177/614 reads (29%) | called by muse, mutect2, varscan2
- CDH23 | c.414C>T p.S138= | Silent (SNP) | VAF 95/389 reads (24%) | catalogued as rs745908110; ClinVar: likely benign; called by muse, mutect2
- CHRNA6 | c.1002G>A p.T334= | Silent (SNP) | VAF 64/483 reads (13%) | catalogued as rs775611153, COSV52379814, COSV52381408; called by muse, mutect2, varscan2
- COL14A1 | c.3588C>T p.D1196= | Silent (SNP) | VAF 85/356 reads (24%) | catalogued as rs756641610; called by muse, mutect2, varscan2
- DLGAP2 | c.255C>T p.S85= | Silent (SNP) | VAF 75/617 reads (12%) | catalogued as rs759970752, COSV70097024; called by muse, mutect2, varscan2
- DLGAP2 | c.933G>A p.T311= | Silent (SNP) | VAF 168/715 reads (23%) | catalogued as rs746806848; called by muse, mutect2, varscan2
- DNAI4 | c.2241T>G p.T747= | Silent (SNP) | VAF 86/407 reads (21%) | catalogued as COSV64031327; called by muse, mutect2, varscan2
- DSEL | c.937T>C p.L313= | Silent (SNP) | VAF 120/446 reads (27%) | catalogued as COSV59492740, COSV59493655; called by muse, varscan2
- ERICH3 | c.2778G>A p.A926= | Silent (SNP) | VAF 92/493 reads (19%) | catalogued as rs780828895, COSV58608651; called by muse, mutect2, varscan2
- ERVV-1 | c.720C>T p.F240= | Silent (SNP) | VAF 98/593 reads (17%) | catalogued as rs763422617; called by muse, varscan2
- ERVV-1 | c.879G>A p.T293= | Silent (SNP) | VAF 177/594 reads (30%) | catalogued as rs1389825285; called by muse, varscan2
- FAM90A1 | c.1236C>A p.P412= | Silent (SNP) | VAF 63/429 reads (15%) | called by muse, mutect2, varscan2
- GHR | c.351G>A p.S117= | Silent (SNP) | VAF 184/504 reads (37%) | catalogued as rs759072721, COSV100050021; called by muse, mutect2, varscan2
- INSR | c.3669C>T p.G1223= | Silent (SNP) | VAF 26/233 reads (11%) | catalogued as rs750713967, COSV57170057; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQSEC3 | c.1662C>T p.C554= (on ENST00000538872 / NM_001170738.2; = p.C251= on NM_015232.1) | Silent (SNP) | VAF 151/633 reads (24%) | called by muse, mutect2, varscan2
- KIF1A | c.3273C>T p.D1091= | Silent (SNP) | VAF 45/276 reads (16%) | catalogued as rs773965535, COSV57488507; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC4B | c.2037C>T p.S679= | Silent (SNP) | VAF 223/686 reads (33%) | catalogued as COSV65351216; called by muse, mutect2, varscan2
- MAGEB5 | c.289T>C p.L97= | Silent (SNP) | VAF 50/420 reads (12%) | catalogued as COSV66868829; called by muse, mutect2, varscan2
- METTL26 | c.243C>T p.A81= | Silent (SNP) | VAF 117/420 reads (28%) | catalogued as rs1243889404; called by muse, mutect2, varscan2
- MIOX | c.63G>T p.V21= | Silent (SNP) | VAF 82/308 reads (27%) | called by muse, mutect2, varscan2
- MRC1 | c.357C>T p.Y119= | Silent (SNP) | VAF 111/563 reads (20%) | catalogued as rs782202601; called by muse, mutect2, varscan2
- MYOD1 | c.93C>T p.D31= | Silent (SNP) | VAF 117/540 reads (22%) | catalogued as COSV51454789; called by muse, mutect2, varscan2
- NPBWR1 | c.357C>T p.N119= | Silent (SNP) | VAF 56/452 reads (12%) | catalogued as rs1186617923; called by muse, mutect2, varscan2
- NYAP2 | c.1053C>T p.D351= | Silent (SNP) | VAF 28/340 reads (8%) | catalogued as COSV99796465; called by muse, mutect2
- OR4C15 | c.735T>C p.T245= (on ENST00000314644; = p.T191= on NM_001001920.2) | Silent (SNP) | VAF 42/406 reads (10%) | catalogued as COSV58951027; called by muse, mutect2, varscan2
- OR5H8 | c.666C>G p.L222= | Silent (SNP) | VAF 34/282 reads (12%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.529C>T p.L177= | Silent (SNP) | VAF 50/416 reads (12%) | called by muse, mutect2, varscan2
- PLCL1 | c.2797C>A p.R933= | Silent (SNP) | VAF 27/401 reads (7%) | called by muse, mutect2
- PLEKHG5 | c.621G>A p.P207= (on ENST00000400915 / NM_001042663.3; = p.P170= on NM_020631.6) | Silent (SNP) | VAF 114/480 reads (24%) | catalogued as rs773624292; called by muse, mutect2, varscan2
- PREX2 | c.3279A>G p.E1093= | Silent (SNP) | VAF 73/387 reads (19%) | called by muse, mutect2, varscan2
- PXDN | c.4411T>C p.L1471= | Silent (SNP) | VAF 62/265 reads (23%) | catalogued as rs755720043, COSV53228523, COSV53240068, COSV99413689; called by muse, mutect2, varscan2
- RAP1B | c.378A>G p.V126= | Silent (SNP) | VAF 39/422 reads (9%) | called by muse, mutect2
- RREB1 | c.1965G>A p.S655= | Silent (SNP) | VAF 43/510 reads (8%) | catalogued as rs548023559, COSV100619283; called by muse, mutect2
- SBDS | c.429G>A p.S143= | Silent (SNP) | VAF 43/335 reads (13%) | catalogued as rs146780418; called by muse, mutect2, varscan2
- SELENOI | c.147G>A p.A49= | Silent (SNP) | VAF 47/197 reads (24%) | catalogued as rs372437710, COSV99564304; called by muse, mutect2, varscan2
- SGCZ | c.690A>T p.G230= | Silent (SNP) | VAF 57/286 reads (20%) | called by muse, mutect2, varscan2
- SHROOM4 | c.3405G>A p.E1135= | Silent (SNP) | VAF 122/500 reads (24%) | catalogued as rs1557248878; called by muse, mutect2, varscan2
- SLC16A11 | c.927G>A p.P309= (on ENST00000308009; = p.P285= on NM_153357.3) | Silent (SNP) | VAF 90/633 reads (14%) | called by muse, mutect2, varscan2
- SOX17 | c.906G>A p.S302= | Silent (SNP) | VAF 164/697 reads (24%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.3378A>G p.E1126= | Silent (SNP) | VAF 149/556 reads (27%) | called by muse, mutect2, varscan2
- SPEG | c.1107G>A p.A369= | Silent (SNP) | VAF 82/677 reads (12%) | catalogued as rs368196077; called by muse, mutect2, varscan2
- STYXL2 | c.1401C>T p.R467= | Silent (SNP) | VAF 159/612 reads (26%) | called by muse, mutect2, varscan2
- SYNE2 | c.18891C>T p.T6297= | Silent (SNP) | VAF 74/238 reads (31%) | called by muse, mutect2, varscan2
- TPTE | c.156G>T p.V52= | Silent (SNP) | VAF 28/528 reads (5%) | called by muse, mutect2
- USP6NL | c.1305G>A p.S435= | Silent (SNP) | VAF 71/653 reads (11%) | catalogued as COSV53209145; called by muse, mutect2, varscan2
- VSX1 | c.264C>T p.F88= | Silent (SNP) | VAF 74/679 reads (11%) | called by muse, mutect2, varscan2
- WNT8B | c.960C>T p.R320= | Silent (SNP) | VAF 62/540 reads (11%) | called by muse, mutect2, varscan2
- XRN1 | c.930T>A p.L310= | Silent (SNP) | VAF 44/204 reads (22%) | called by muse, mutect2
- ZMIZ2 | c.1722C>T p.S574= | Silent (SNP) | VAF 34/412 reads (8%) | catalogued as rs750835591; called by muse, mutect2
- ZNF530 | c.192G>A p.T64= | Silent (SNP) | VAF 27/415 reads (7%) | catalogued as rs777683891; called by muse, mutect2
- DCHS2 | n.2515T>C | RNA (SNP) | VAF 33/230 reads (14%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+983C>A | Intron (SNP) | VAF 115/603 reads (19%) | catalogued as COSV60575910; called by muse, mutect2, varscan2
- NAALAD2 | c.1278+85T>C | Intron (SNP) | VAF 23/309 reads (7%) | called by muse, mutect2
- PKD1L2 | chr16:81139640 C>T | 5'Flank (SNP) | VAF 54/360 reads (15%) | catalogued as rs545106863; called by muse, mutect2, varscan2
- SPATA1 | c.-48del | 5'UTR (DEL) | VAF 49/228 reads (21%) | catalogued as rs1045281118; called by mutect2, pindel, varscan2
